Gene-level copy-number profile of tumor specimen HCM-CSHL-0089-C25-01A from HCMI case HCM-CSHL-0089-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.5 years (22,825 days).
Specimen HCM-CSHL-0089-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99c4df88-2d40-43e2-8198-016fd19eb63c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0089-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/3dfd2621-be26-4295-b04d-28e1a188c3f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 14,658; copy number 2: 42,225; copy number 3: 1,214; copy number 4: 267; copy number 5: 31.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:131,910–206,392, 5 genes: CICP18, AL035696.2, AL035696.3, AL035696.4, AL035696.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:102,204,502–102,253,750, 3 genes, copy number 5 (within-gene range 3–5): RRM2B, UBR5-AS1, SUMO2P19.
- chr18:31,718,893–32,470,882, 28 genes, copy number 5: RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.

Autosomal genes at a single copy (total copy number 1): 12,314. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
